Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A6B6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A6B6-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

OUTPATIENT

Clinical Diagnosis & History:

T1 HG no muscle on prior biopsy.

Specimens Submitted:

1: Right posterior bladder wall tumor, TURBT

DIAGNOSIS:

1. Right posterior bladder wall tumor, TURBT:

Part # 1

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

Papillary and flat

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

Non-Neoplastic Mucosa:

Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)

*IBD-0-3
Carcinoma, urothelial
8/20/13
Site Bladder, posterior
wall C67.4
JW 6/18/13*

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1.) The specimen is received in hank's solution, labelled " Right posterior bladder wall tumor " and consists of multiple piece(s) of irregular tan-brown soft tissue fragments measuring 1.1 x 1.0 x 0.7 cm in aggregate. The specimen is entirely submitted in two cassettes. Some tissue was taken by T P S.

Summary of Sections:

Part 1: Right posterior bladder wall tumor, TURBT

Block

Sect. Site

PCs

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

2

{not entered}

12

Source: NCI Genomic Data Commons file 514554ca-6b84-45c5-8190-5476d6c422e8 (TCGA-DK-A6B6.D7E1CBFA-6E00-48AF-804D-6AD61CA65506.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).